CCDI case PBBWMI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9f5fe159-0199-4a59-b0ab-6685c7425a1e

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.2 years (3,005 days).

Biospecimens (3 samples)
- Sample 0DJ8KO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJKK7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJKKO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
